Somatic mutation profile of tumor specimen TCGA-BG-A0VV-01A (aliquot TCGA-BG-A0VV-01A-21D-A122-09) from TCGA case TCGA-BG-A0VV, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G1; Age at diagnosis: 53.6 years (19,581 days).
Specimen TCGA-BG-A0VV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c796110e-e1ac-4fef-b2c7-6b44237cfbc5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BG-A0VV-10A (Blood Derived Normal), aliquot TCGA-BG-A0VV-10A-01D-A122-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5b713002-fa95-4e82-aea2-45ed565d2351

The open-access MAF lists 43 somatic variants for this specimen: 36 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 25, Nonsense Mutation 8, Silent 7, Frame Shift Ins 1, Splice Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL4A5 | c.1276G>A p.G426R | Missense Mutation (SNP) | VAF 45/130 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs104886111, CM052208, COSV60358773; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- FGFR2 | c.755C>G p.S252W | Missense Mutation (SNP) | VAF 65/92 reads (71%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs79184941, CM950458, CM970526, COSV60638319; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3R1 | c.1746-24_1764del p.X582_splice (on ENST00000521381 / NM_181523.3; = p.X312_splice on NM_181504.4) | Splice Site (DEL) | VAF 120/571 reads (21%) | hotspot (GDC flag); called by mutect2, pindel
- AC013489.1 | c.760C>T p.R254W | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs773541670, COSV51552021; called by muse, mutect2, varscan2
- ADCY1 | c.1036C>T p.R346C | Missense Mutation (SNP) | VAF 40/114 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs775522653, COSV52034884; called by muse, mutect2
- ANP32B | c.458A>T p.Q153L | Missense Mutation (SNP) | VAF 104/288 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.065); catalogued as COSV59587026; called by muse, mutect2, varscan2
- ARID1A | c.4417C>T p.Q1473* | Nonsense Mutation (SNP) | VAF 18/70 reads (26%) | catalogued as COSV61376801; called by muse, mutect2, varscan2
- ARID1A | c.5548dup p.D1850Gfs*4 | Frame Shift Ins (INS) | VAF 21/62 reads (34%) | catalogued as rs758608743; called by mutect2, varscan2
- BMP8B | c.439C>T p.R147W | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs779032226, COSV59594110; called by mutect2, varscan2
- CCDC102B | c.173G>A p.C58Y | Missense Mutation (SNP) | VAF 47/146 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs775750166, COSV60145437; called by muse, mutect2, varscan2
- CHD4 | c.3445C>T p.R1149W (on ENST00000357008 / NM_001363606.2; = p.R1162W on NM_001273.5) | Missense Mutation (SNP) | VAF 46/144 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58894467; called by muse, mutect2, varscan2
- CNOT9 | c.246G>T p.L82F | Missense Mutation (SNP) | VAF 96/306 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55300458; called by muse, mutect2, varscan2
- CRYBB2 | c.199T>A p.C67S | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.136); catalogued as COSV68005537; called by muse, mutect2, varscan2
- CSNK1D | c.503G>A p.R168H | Missense Mutation (SNP) | VAF 89/343 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV53923399; called by muse, mutect2, varscan2
- CTCF | c.1369C>T p.R457* | Nonsense Mutation (SNP) | VAF 21/105 reads (20%) | catalogued as COSV50461417; called by muse, mutect2
- DPYSL5 | c.1579G>A p.D527N | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV56513518; called by muse, mutect2, varscan2
- DSCAML1 | c.5914C>T p.R1972* (on ENST00000321322; = p.R1912* on NM_020693.4) | Nonsense Mutation (SNP) | VAF 14/44 reads (32%) | catalogued as rs1450422367, COSV100355028; called by muse, mutect2
- ECT2L | c.155T>A p.L52* | Nonsense Mutation (SNP) | VAF 101/300 reads (34%) | catalogued as rs577253266, COSV62882917, COSV62885423; called by muse, mutect2, varscan2
- HPR | c.201C>A p.Y67* | Nonsense Mutation (SNP) | VAF 127/504 reads (25%) | catalogued as COSV57183379; called by muse, mutect2, varscan2
- IRX5 | c.1313A>G p.H438R | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV58059257; called by muse, mutect2, varscan2
- LLGL1 | c.2756G>A p.R919H | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.34); catalogued as rs749223309, COSV57498875; called by muse, mutect2, varscan2
- MECOM | c.247C>T p.R83* | Nonsense Mutation (SNP) | VAF 40/321 reads (12%) | catalogued as COSV72110655, COSV72110930; called by muse, varscan2
- NSDHL | c.749C>T p.A250V | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs200068633, COSV64743972; called by muse, mutect2, varscan2
- OTOF | c.3239G>A p.R1080H (on ENST00000272371 / NM_194248.3; = p.R333H on NM_004802.4) | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as rs397515598, CM094709, COSV55503487; called by muse, mutect2, varscan2
- PCDHA4 | c.845C>G p.S282* | Nonsense Mutation (SNP) | VAF 39/147 reads (27%) | catalogued as rs782714684, COSV63542980, COSV63545513; called by muse, mutect2, varscan2
- PIK3R1 | c.1702C>A p.P568T (on ENST00000521381 / NM_181523.3; = p.P298T on NM_181504.4) | Missense Mutation (SNP) | VAF 106/350 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57132396; called by muse, mutect2, varscan2
- RAB40AL | c.295C>T p.R99C | Missense Mutation (SNP) | VAF 52/241 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.146); catalogued as rs780406762, COSV54434858; called by muse, mutect2, varscan2
- RDH8 | c.629C>A p.T210N (on ENST00000651512; = p.T190N on NM_015725.4) | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV50675780; called by muse, mutect2, varscan2
- RINT1 | c.1504A>C p.K502Q | Missense Mutation (SNP) | VAF 120/345 reads (35%) | SIFT tolerated (0.64); PolyPhen benign (0.034); catalogued as COSV57559129; called by muse, mutect2, varscan2
- SEMA3A | c.1130G>C p.R377P | Missense Mutation (SNP) | VAF 72/219 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54875316, COSV54876893; called by muse, mutect2, varscan2
- SI | c.3961G>T p.V1321F | Missense Mutation (SNP) | VAF 133/394 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV52285162; called by muse, mutect2, varscan2
- SOS2 | c.1159C>T p.R387* | Nonsense Mutation (SNP) | VAF 28/576 reads (5%) | catalogued as COSV53564006; called by muse, mutect2
- SVEP1 | c.10450C>T p.R3484C | Missense Mutation (SNP) | VAF 45/123 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs189890058, COSV52839306; called by muse, mutect2, varscan2
- SYCP1 | c.1208A>C p.D403A | Missense Mutation (SNP) | VAF 61/241 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV65698705; called by muse, mutect2, varscan2
- TPT1 | c.110G>T p.S37I | Missense Mutation (SNP) | VAF 98/344 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); catalogued as COSV58538925; called by muse, mutect2, varscan2
- MAPK14 | c.146_163del p.R49_K54del | In Frame Del (DEL) | VAF 53/245 reads (22%) | called by mutect2, pindel, varscan2
- ARSG | c.1329C>T p.S443= | Silent (SNP) | VAF 88/232 reads (38%) | catalogued as COSV50930426; called by muse, mutect2, varscan2
- GRIA3 | c.63G>T p.G21= | Silent (SNP) | VAF 86/264 reads (33%) | catalogued as COSV52067427; called by muse, mutect2, varscan2
- KCND3 | c.843C>T p.D281= | Silent (SNP) | VAF 8/114 reads (7%) | catalogued as rs1287255718, COSV56176900; called by muse, mutect2
- MROH2B | c.2913G>A p.Q971= | Silent (SNP) | VAF 111/351 reads (32%) | catalogued as COSV68185819; called by muse, mutect2, varscan2
- MTAP | c.654G>C p.A218= | Silent (SNP) | VAF 35/115 reads (30%) | catalogued as COSV66477958; called by muse, mutect2, varscan2
- SCN7A | c.2076C>A p.T692= | Silent (SNP) | VAF 61/207 reads (29%) | catalogued as COSV69272648, COSV69274041; called by muse, mutect2, varscan2
- TM7SF2 | c.597C>T p.I199= | Silent (SNP) | VAF 58/188 reads (31%) | catalogued as COSV54208035, COSV99659564; called by muse, mutect2, varscan2
